Somatic mutation profile of tumor specimen TARGET-30-PALRSD-01A (aliquot TARGET-30-PALRSD-01A-01D) from TARGET case TARGET-30-PALRSD, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 7.5 years (2,726 days).
Specimen TARGET-30-PALRSD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b93b8df3-8f3a-41b6-a9d9-9a4e8a6508fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PALRSD-10A (Blood Derived Normal), aliquot TARGET-30-PALRSD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab289f3b-f208-4821-8df9-81eda742f70b

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Splice Site 1, Silent 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MMRN1 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs771204123, COSV53333838, COSV53341468; called by mutect2, varscan2
- NAA50 | c.265+1G>C p.X89_splice | Splice Site (SNP) | VAF 11/94 reads (12%) | catalogued as COSV53787030; called by muse, mutect2, varscan2
- PITX2 | c.434G>A p.R145H (on ENST00000354925 / NM_001204397.1; = p.R152H on NM_000325.6) | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60742016; called by mutect2, varscan2
- PLK1 | c.1593G>T p.Q531H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55623940; called by mutect2, varscan2
- SGSM1 | c.1607A>G p.K536R | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.219); catalogued as COSV68512642; called by muse, mutect2
- SYCP1 | c.1190G>T p.R397I | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65700332; called by muse, mutect2, varscan2
- TNC | c.2515A>T p.I839F | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.392); catalogued as COSV60789151; called by muse, mutect2, varscan2
- ZNF347 | c.1586C>A p.A529E | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.153); catalogued as COSV100498502, COSV61970437; called by muse, mutect2, varscan2
- FZD1 | c.933C>T p.F311= | Silent (SNP) | VAF 12/136 reads (9%) | catalogued as rs763610283, COSV55309349; called by muse, mutect2
- AC073310.1 | n.135G>A | RNA (SNP) | VAF 31/154 reads (20%) | called by muse, mutect2, varscan2
